Somatic mutation profile of tumor specimen TCGA-MK-A4N9-01A (aliquot TCGA-MK-A4N9-01A-11D-A257-08) from TCGA case TCGA-MK-A4N9, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 41.8 years (15,255 days).
Specimen TCGA-MK-A4N9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ecd095c5-2f1c-4ee9-a1fd-9a131ff79e16.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-MK-A4N9-10A (Blood Derived Normal), aliquot TCGA-MK-A4N9-10A-01D-A25A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/94badf5b-abce-4701-9d74-9a8d5d3d97b0

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CSMD1 | c.235C>G p.L79V | Missense Mutation (SNP) | VAF 4/91 reads (4%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.997); catalogued as COSV68208228; called by muse, mutect2
- RSPH6A | c.1099G>A p.E367K | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.821); catalogued as COSV55572099; called by muse, mutect2, varscan2
- TGFBI | c.1230G>A p.L410= | Silent (SNP) | VAF 15/107 reads (14%) | catalogued as COSV59351480; called by muse, mutect2, varscan2
